Somatic mutation profile of tumor specimen TCGA-4G-AAZO-01A (aliquot TCGA-4G-AAZO-01A-12D-A417-09) from TCGA case TCGA-4G-AAZO, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 71.2 years (25,989 days).
Specimen TCGA-4G-AAZO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ca1adbc-7a68-47f1-a217-1d1159f245d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4G-AAZO-11A (Solid Tissue Normal), aliquot TCGA-4G-AAZO-11A-11D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffda4d67-328a-488e-bc4a-2dd91ce7a727

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 28, Silent 10, Frame Shift Del 3, Frame Shift Ins 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRF3 | c.1378A>G p.I460V (on ENST00000311519 / NM_001145168.1; = p.I261V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1465806731; called by muse, mutect2
- COL6A1 | c.1951G>C p.V651L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.193); catalogued as rs767358249; called by muse, mutect2
- GBF1 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs369887575; called by mutect2, varscan2
- GREM1 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55714462; called by muse, mutect2, varscan2
- IMPG2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV51981373; called by muse, mutect2, varscan2
- LRP8 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.713); catalogued as COSV100036324; called by muse, mutect2, varscan2
- LYSMD4 | c.175G>A p.G59S (on ENST00000409796 / NM_001284417.2; = p.A29= on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100230502, COSV100230655; called by muse, mutect2, varscan2
- MED13 | c.4291G>A p.V1431I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs1480916223; called by muse, mutect2, varscan2
- PAX6 | c.268T>C p.Y90H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748252607; called by muse, mutect2
- UXS1 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs762838871, COSV51680401; called by muse, mutect2, varscan2
- XKR4 | c.489C>A p.S163R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100534068; called by muse, mutect2, varscan2
- ZNF208 | c.739C>A p.H247N | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs759285591, COSV101237012; called by muse, mutect2, varscan2
- ARHGEF5 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- ARID1A | c.6747dup p.E2250Rfs*28 | Frame Shift Ins (INS) | VAF 9/13 reads (69%) | called by mutect2, varscan2
- BAP1 | c.1356_1357delinsT p.E454Sfs*117 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | called by pindel, varscan2*
- BIRC6 | c.8827A>G p.R2943G | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CCDC178 | c.315T>A p.D105E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- CCNA2 | c.1192T>C p.Y398H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CNTNAP5 | c.1679del p.S560Tfs*80 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- CSF1 | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EAPP | c.179A>C p.E60A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EXTL3 | c.92G>A p.W31* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- FRG2C | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- IL10RA | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2
- NEB | c.2214T>A p.H738Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PPL | c.1098C>A p.D366E | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC12A7 | c.1592A>G p.Q531R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SORBS1 | c.17A>T p.D6V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); called by muse, varscan2
- SYNE1 | c.15325G>T p.A5109S (on ENST00000367255 / NM_182961.4; = p.A5038S on NM_033071.3) | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TLN1 | c.7237G>A p.A2413T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.11); called by mutect2, varscan2
- TRMT5 | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZHX3 | c.884C>G p.A295G | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF112 | c.1803_1804del p.R601Sfs*11 (on ENST00000337401 / NM_001083335.2; = p.R595Sfs*11 on NM_013380.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by pindel, varscan2
- ZNF185 | c.290_291insTA p.S98Tfs*23 | Frame Shift Ins (INS) | VAF 24/54 reads (44%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.3460C>T p.L1154= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs757105827; called by muse, mutect2, varscan2
- ERBB2 | c.2263T>C p.L755= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV54062219, COSV54066696; called by muse, mutect2, varscan2
- GPR179 | c.1950C>T p.D650= (on ENST00000621958; = p.D649= on NM_001004334.4) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs372049950; ClinVar: uncertain significance; called by muse, mutect2
- LARS2 | c.678A>T p.S226= | Silent (SNP) | VAF 19/24 reads (79%) | called by muse, mutect2, varscan2
- MAMDC4 | c.3471C>A p.G1157= (on ENST00000445819; = p.G1078= on NM_206920.3) | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- NNT | c.3216A>G p.T1072= | Silent (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- NT5C1B | c.615C>T p.R205= (on ENST00000359846 / NM_001199086.2; = p.R145= on NM_033253.4) | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs760520328; called by muse, mutect2, varscan2
- OR5I1 | c.558G>A p.L186= | Silent (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1308A>G p.R436= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs1469516977, COSV67316579; called by muse, varscan2
- ZNF804A | c.2163T>A p.T721= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2
